Gene-level copy-number profile of tumor specimen TCGA-XE-A8H4-01A from TCGA case TCGA-XE-A8H4, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 23.9 years (8,728 days).
Specimen TCGA-XE-A8H4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.f60272df-9864-47f8-84b4-cc567947a2a7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XE-A8H4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fa19f19d-7328-40f0-867f-28f6732e4a1e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,494; copy number 2: 12,318; copy number 3: 22,375; copy number 4: 12,785; copy number 5: 8,515; copy number 6: 449; copy number 7: 57; copy number 8: 97; copy number 10: 476; copy number 15: 16; copy number 21: 232.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XE-A8H4-01A-31D-A434-01): tumor purity 0.27, ploidy 2.97, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 878 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:58,023,881–58,181,616, 1 gene, copy number 7 (within-gene range 6–7): OR9Q1.
- chr11:58,108,720–59,291,333, 56 genes, copy number 7: OR9I3P, OR9I1, OR9I2P, OR5BL1P, OR9Q2, OR1S2, OR1S1, OR10Q1, EIF4A2P3, OR10W1, OR10Q2P, OR5BC1P, OR5B19P, OR5B10P, AP000435.1, OR5B17, OR5B1P, OR5B15P, OR5B3, OR5B2, OR5B12, AP003557.2, AP003557.1, OR5B21, LPXN, ZFP91, ZFP91-CNTF, AP001350.1, CNTF, AP001350.2, GLYAT, AP000445.1, AP000445.2, TMA16P1, GLYATL2, GLYATL1P2, GLYATL1, AP001652.1, AP001636.3, AP001636.2, GLYATL1P1, AP001636.1, GLYATL1P4, GLYATL1B, FAM111B, FAM111A-DT, AP001258.1, FAM111A, DTX4, MPEG1, RN7SL42P, WARS1P1, SLC25A47P1, AP002358.1, AP002358.2, RN7SL435P.
- chr12:280,057–32,993,754, 821 genes, copy number 8–21 (within-gene range 5–21) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,494. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
